Somatic mutation profile of tumor specimen C3L-02701-02 (aliquot CPT0227930007) from CPTAC case C3L-02701, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G2; Age at diagnosis: 72.1 years (26,345 days).
Specimen C3L-02701-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7cb13217-3a19-47aa-9186-be36edb6b93e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-02701-31 (Blood Derived Normal), aliquot CPT0228080006; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e37b37f8-7bce-4171-a092-debac6415579

The open-access MAF lists 65 somatic variants for this specimen: 44 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 39, Silent 18, Splice Site 2, 5'UTR 2, Intron 1, Nonsense Mutation 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 56/543 reads (10%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- CACNA1E | c.3811C>T p.R1271C | Missense Mutation (SNP) | VAF 18/568 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62383166; called by muse, mutect2
- CATSPERE | c.151T>C p.W51R | Missense Mutation (SNP) | VAF 32/283 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1435630908; called by muse, mutect2
- CRYBA4 | c.303C>T p.N101= | Splice Region (SNP) | VAF 66/763 reads (9%) | catalogued as rs1484461662, COSV61322740; called by muse, mutect2
- DDI1 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 58/551 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.724); catalogued as rs778186886, COSV56386828; called by muse, mutect2, varscan2
- DSCAM | c.2884G>A p.A962T | Missense Mutation (SNP) | VAF 82/1120 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs917866485, COSV68022517, COSV68029335; called by muse, mutect2
- EGFLAM | c.1543G>A p.A515T | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.689); catalogued as rs773215630, COSV59306350; called by muse, mutect2, varscan2
- FOXE1 | c.1108G>A p.V370M | Missense Mutation (SNP) | VAF 102/1274 reads (8%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.57); catalogued as COSV100909942; called by muse, mutect2
- GDF2 | c.88C>T p.R30* | Nonsense Mutation (SNP) | VAF 18/178 reads (10%) | catalogued as rs782274691; called by muse, mutect2
- KIF17 | c.2825G>A p.R942Q | Missense Mutation (SNP) | VAF 70/1246 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs146340669; called by muse, mutect2
- KIF26A | c.2366C>T p.T789M | Missense Mutation (SNP) | VAF 60/620 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765014920, COSV59466324; called by muse, mutect2
- MTOR | c.6130G>A p.V2044M | Missense Mutation (SNP) | VAF 30/299 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs868627779; called by muse, mutect2, varscan2
- NEDD9 | c.2477G>A p.R826H | Missense Mutation (SNP) | VAF 30/296 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs758066091; called by muse, varscan2
- PCDHGA8 | c.1820G>A p.R607H | Missense Mutation (SNP) | VAF 60/1069 reads (6%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.047); catalogued as rs1026935408; called by muse, mutect2
- PCYT1A | c.152T>C p.I51T | Missense Mutation (SNP) | VAF 27/319 reads (8%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs780253017; called by muse, mutect2
- PDIA4 | c.788C>T p.P263L | Missense Mutation (SNP) | VAF 36/893 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as COSV53727087; called by muse, mutect2
- SGK1 | c.593G>A p.R198Q | Missense Mutation (SNP) | VAF 50/592 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs775999779, COSV99397572; called by muse, mutect2
- SIGLEC15 | c.956G>A p.R319Q | Missense Mutation (SNP) | VAF 48/661 reads (7%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.001); catalogued as rs775151990, COSV101248703, COSV101248769; called by muse, mutect2
- SULF1 | c.1130C>A p.P377H | Missense Mutation (SNP) | VAF 114/730 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV52675160; called by muse, mutect2, varscan2
- VIL1 | c.1483C>T p.R495C | Missense Mutation (SNP) | VAF 28/370 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs768874816, COSV50288224, COSV99945854; called by muse, mutect2
- ZBED2 | c.157C>T p.R53W | Missense Mutation (SNP) | VAF 35/385 reads (9%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.63); catalogued as rs967555755; called by muse, mutect2
- ZNF471 | c.266C>G p.S89C | Missense Mutation (SNP) | VAF 10/113 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV57290724, COSV57292730; called by muse, mutect2
- ABCF2-H2BE1 | c.155-1G>T p.X52_splice | Splice Site (SNP) | VAF 105/1124 reads (9%) | called by muse, mutect2
- ACVR1B | c.839T>C p.L280P | Missense Mutation (SNP) | VAF 39/382 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATP11C | c.722C>A p.S241Y | Missense Mutation (SNP) | VAF 17/122 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- DDX6 | c.1157G>A p.R386H | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DNAH8 | c.8949G>T p.R2983S | Missense Mutation (SNP) | VAF 50/868 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.142); called by muse, mutect2
- FIGN | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 35/535 reads (7%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, mutect2
- GPR135 | c.1008G>T p.M336I | Missense Mutation (SNP) | VAF 46/590 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2
- IGLV10-54 | c.137A>G p.N46S | Missense Mutation (SNP) | VAF 65/669 reads (10%) | SIFT tolerated, low confidence (0.94); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IK | c.212C>A p.A71D | Missense Mutation (SNP) | VAF 18/414 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); called by muse, mutect2
- ITGA9 | c.1169A>T p.D390V | Missense Mutation (SNP) | VAF 82/922 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); called by muse, mutect2
- JARID2 | c.3073G>A p.V1025M | Missense Mutation (SNP) | VAF 58/668 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.882); called by muse, mutect2
- KANK1 | c.1858T>G p.L620V | Missense Mutation (SNP) | VAF 55/554 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.03); called by muse, mutect2
- KAT8 | c.1228A>G p.K410E | Missense Mutation (SNP) | VAF 54/547 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, varscan2
- KIAA0232 | c.500C>T p.A167V | Missense Mutation (SNP) | VAF 19/362 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.942); called by muse, mutect2
- LCN12 | c.55G>A p.A19T | Missense Mutation (SNP) | VAF 68/742 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.01); called by muse, mutect2
- LTBP1 | c.2728C>A p.Q910K (on ENST00000404816 / NM_206943.4; = p.Q584K on NM_000627.4) | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.25); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NPS | c.9-1G>T p.X3_splice | Splice Site (SNP) | VAF 35/276 reads (13%) | called by muse, mutect2, varscan2
- SLC22A6 | c.866A>G p.Q289R | Missense Mutation (SNP) | VAF 66/586 reads (11%) | SIFT tolerated (0.65); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- SYMPK | c.3283A>G p.M1095V | Missense Mutation (SNP) | VAF 55/546 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.093); called by muse, mutect2, varscan2
- TP53 | c.757dup p.T253Nfs*11 | Frame Shift Ins (INS) | VAF 71/642 reads (11%) | called by mutect2, pindel, varscan2
- ULK1 | c.917G>A p.S306N | Missense Mutation (SNP) | VAF 47/766 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.962); called by muse, mutect2
- ZNF835 | c.1312C>T p.R438C | Missense Mutation (SNP) | VAF 76/871 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- C1QTNF5 | c.420C>T p.T140= | Silent (SNP) | VAF 53/517 reads (10%) | catalogued as rs1228782830, COSV60989870; called by muse, mutect2, varscan2
- ELFN1 | c.1995C>T p.A665= | Silent (SNP) | VAF 22/215 reads (10%) | called by muse, mutect2, varscan2
- FOXL3 | c.396C>T p.R132= | Silent (SNP) | VAF 16/132 reads (12%) | catalogued as COSV72563085; called by muse, mutect2
- GRM1 | c.1005C>T p.N335= | Silent (SNP) | VAF 66/786 reads (8%) | catalogued as rs770979982, COSV51186172; called by muse, mutect2
- HEPH | c.2022A>G p.A674= (on ENST00000343002; = p.A407= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 45/284 reads (16%) | called by muse, mutect2, varscan2
- ICA1L | c.132G>A p.A44= | Silent (SNP) | VAF 30/517 reads (6%) | catalogued as COSV64173336; called by muse, mutect2
- KRTAP20-2 | c.57C>T p.G19= | Silent (SNP) | VAF 82/924 reads (9%) | catalogued as rs1194592664, COSV58182517; called by muse, mutect2
- LRP2 | c.13605G>T p.V4535= | Silent (SNP) | VAF 142/806 reads (18%) | called by muse, varscan2
- NUDT5 | c.582C>T p.D194= | Silent (SNP) | VAF 56/835 reads (7%) | catalogued as rs376827328; called by muse, mutect2
- OR8B4 | c.795C>A p.G265= | Silent (SNP) | VAF 62/626 reads (10%) | catalogued as COSV62069300; called by muse, mutect2
- PKN1 | c.2250C>T p.T750= | Silent (SNP) | VAF 16/316 reads (5%) | catalogued as rs200074602; called by muse, mutect2
- SCUBE1 | c.2190C>T p.G730= | Silent (SNP) | VAF 48/646 reads (7%) | called by muse, mutect2
- SLC16A3 | c.174C>T p.S58= | Silent (SNP) | VAF 66/926 reads (7%) | catalogued as rs368718021; called by muse, mutect2
- TFR2 | c.156C>T p.C52= | Silent (SNP) | VAF 9/107 reads (8%) | catalogued as rs1324111442; called by muse, mutect2
- UBASH3A | c.1884T>C p.N628= | Silent (SNP) | VAF 34/303 reads (11%) | catalogued as rs376352061; called by muse, mutect2, varscan2
- WAPL | c.652A>C p.R218= | Silent (SNP) | VAF 26/429 reads (6%) | called by muse, mutect2
- ZFP92 | c.963G>A p.A321= | Silent (SNP) | VAF 74/415 reads (18%) | called by muse, mutect2, varscan2
- ZNF497 | c.519G>A p.A173= | Silent (SNP) | VAF 82/1002 reads (8%) | catalogued as COSV99568405; called by muse, mutect2
- DPEP3 | c.-6C>T | 5'UTR (SNP) | VAF 26/390 reads (7%) | catalogued as rs960510134; called by muse, mutect2
- MTMR10 | c.-4C>T | 5'UTR (SNP) | VAF 13/378 reads (3%) | called by muse, mutect2
- TTN | c.10360+1496C>T | Intron (SNP) | VAF 23/302 reads (8%) | catalogued as rs760734881; called by muse, mutect2
